Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A922, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A922-01A (Primary Tumor).

[page 1 of 2]
Collect date:

ICD-O-3

Adenocarcinoma, tubular
82113

Site Gastric antrum
C16.3

gn 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

1-Stomach:

Adenocarcinoma with the following features:

Bormann type: III

Histologic pattern:

Tubular

Histologic grade: II, moderately differentiated

Lauren classification: intestinal type

Largest tumor size: 4.0 cm

Ulceration: present

Local invasion:

To muscularis propria

And other structures: duodenum and peripancreatic fat tissue

Tumor invasion type

Expansive

Inflammatory response

Moderate

Tumor implant in perivisceral fat

Not observed

Proximal margin

Uninvolved by neoplasia

Distal margin

Uninvolved by neoplasia

Neural invasion

Absent

Lymphatic invasion

Present

Blood vessel invasion

Doubtful

Greater omentum

Uninvolved by neoplasia

Lymph nodes:

Involved by neoplasia: 1/8

Lymph node clusters: not observed

Soft tissue tumor implants: present

Report of examined lymph nodes according to standardization, JGCA-1998:

F- Chain 1 – right paracardic: (0/3)

O- Chain 8a – anterior hepatic artery (antero-superior group): (1/2)

Q- Chain 9 – celiac trunk: (0/3)

[page 2 of 2]
Superior edge of pancreatic body:
- Adenocarcinoma infiltrating connective tissue.

Lymph node:
- Uninvolved by neoplasia.

Esophageal margin:
- Uninvolved by neoplasia.

Spleen:
- Uninvolved by neoplasia.

Diagnostic Discrepancy		✓
IFNA Discrepancy		✓

Source: NCI Genomic Data Commons file 8426e1fe-7b75-4081-867d-a49d11d969f8 (TCGA-VQ-A922.1D7481BE-DEF6-4127-8AD3-2B94D86CFFDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).